CCDI case PBCFXX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/ff9b1162-a5d7-4f8d-b248-d07fa425bac4

Demographics
Sex at birth: female; Vital status: Dead.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Colon, NOS; Age at diagnosis: 16.1 years (5,881 days).

Biospecimens (3 samples)
- Sample 0DR0C5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DR0CE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DR0CS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
